Somatic mutation profile of tumor specimen TCGA-D1-A1O7-01A (aliquot TCGA-D1-A1O7-01A-11D-A14G-09) from TCGA case TCGA-D1-A1O7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 60.3 years (22,037 days).
Specimen TCGA-D1-A1O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 602f23a4-8698-4caf-9e45-c6164ecf13f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1O7-10A (Blood Derived Normal), aliquot TCGA-D1-A1O7-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4070c10a-11fe-4d2c-9999-ae89bfe0e364

The open-access MAF lists 360 somatic variants for this specimen: 254 protein-altering or splice-affecting, 99 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 99, Frame Shift Del 42, Nonsense Mutation 12, Frame Shift Ins 12, Intron 4, Splice Site 3, Splice Region 2, 5'Flank 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.753_756del p.D251Efs*23 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs748789700; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- H3C2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV52517971, COSV52518546; called by muse, mutect2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 20/48 reads (42%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 15/129 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- NPHS1 | c.3250del p.V1084Sfs*59 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs386833935, CD994100; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTC | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.988); catalogued as rs67120076, CM910278, CM971108, COSV99234000; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3010A>G p.M1004V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV55914513; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- AACS | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs546586609, COSV55534170; called by muse, mutect2, varscan2
- ABCB4 | c.2536A>G p.I846V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.173); catalogued as COSV99709904; called by muse, mutect2, varscan2
- ABHD14B | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs199563943; called by muse, mutect2, varscan2
- AC023055.1 | c.1096_1098del p.E366del | In Frame Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs780676938; called by pindel, varscan2
- ACADM | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as rs745793409, CM066529, CM107870, COSV63721605; called by muse, mutect2, varscan2
- ACO2 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99347122; called by muse, mutect2, varscan2
- ADAM12 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as rs200090925, COSV100900139; called by muse, mutect2, varscan2
- ADAMTS1 | c.2791dup p.R931Kfs*9 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs754295488; called by mutect2, varscan2
- ADGRG4 | c.108dup p.G37Wfs*4 | Frame Shift Ins (INS) | VAF 23/69 reads (33%) | catalogued as rs1238901032; called by mutect2, varscan2
- AFG3L2 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301627; called by muse, mutect2
- AKAP17A | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.072); catalogued as rs751358571, COSV100001981; called by muse, mutect2
- ALDH1A2 | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99990501; called by muse, mutect2, varscan2
- AMPD2 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs1303561316, COSV56648615; called by muse, mutect2
- ANK1 | c.5521G>A p.D1841N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs143987736; called by muse, mutect2, varscan2
- ANKFY1 | c.2339G>A p.W780* (on ENST00000341657 / NM_001330063.2; = p.W781* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100492350; called by muse, mutect2, varscan2
- ARID1A | c.6493del p.E2165Rfs*35 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV61380380; called by mutect2, pindel, varscan2
- ARRB2 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV99346961; called by muse, mutect2, varscan2
- ARSD | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 19/136 reads (14%) | catalogued as COSV54200428, COSV99472027; called by muse, mutect2, varscan2
- ASXL1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100038082; called by muse, mutect2, varscan2
- ATP10A | c.1655G>T p.R552M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV100790988; called by muse, mutect2, varscan2
- ATR | c.7226G>A p.C2409Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.24); catalogued as COSV100637788, COSV63387451; called by muse, mutect2
- B3GNT9 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV54629923; called by muse, mutect2
- BCAR1 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50782019; called by muse, mutect2
- BCAT2 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs751627246, COSV60273245; called by muse, mutect2
- BUB3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64363654, COSV64363756; called by muse, mutect2, varscan2
- C11orf52 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782072534, COSV99585555; called by muse, mutect2, varscan2
- CARNS1 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535216231, COSV100321816; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs762553129; called by mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs762805003; called by pindel, varscan2
- CDAN1 | c.1368G>T p.R456S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100661189; called by muse, mutect2
- CDH18 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.81); catalogued as rs368942671, COSV56903027; called by muse, mutect2, varscan2
- CDHR2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.081); catalogued as rs778311985, COSV99991191; called by muse, mutect2, varscan2
- CHD9 | c.2633G>T p.R878I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99528832; called by muse, mutect2
- CHST12 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99324365; called by muse, mutect2, varscan2
- CLUH | c.3262G>A p.A1088T (on ENST00000435359; = p.A1127T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747122833, COSV101425659, COSV70927633; called by muse, mutect2, varscan2
- CNBD1 | c.1004T>A p.I335N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101582167; called by muse, mutect2, varscan2
- CPS1 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772782772, CM114355, COSV99242192; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- CPXM2 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760398201, COSV53859562; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs769538822; called by mutect2, varscan2
- CSRP1 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as rs754606251, COSV100384391, COSV60637840; called by muse, mutect2, varscan2
- CTNNBL1 | c.512T>A p.I171K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100799378; called by muse, mutect2, varscan2
- CTNND1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV62382204; called by muse, mutect2, varscan2
- CUBN | c.2731G>A p.V911M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs768821054, COSV100912217; called by muse, mutect2, varscan2
- CYTH3 | c.848A>G p.K283R (on ENST00000396741; = p.K282R on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV100084066; called by muse, mutect2, varscan2
- DCAF4L1 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV60788471; called by muse, mutect2
- DCHS1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs946492228, COSV100201660; called by muse, mutect2
- DDX56 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.414); catalogued as COSV99345967; called by muse, mutect2
- DNAH7 | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100414277; called by muse, mutect2, varscan2
- DNMT1 | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100531969; called by muse, mutect2
- DNTTIP2 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs780751546, COSV100785146; called by muse, mutect2, varscan2
- DRC7 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100395434; called by muse, mutect2, varscan2
- DYDC2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV99758011; called by mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs768937539; called by pindel, varscan2
- E2F7 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1197715205, COSV100523365; called by muse, mutect2, varscan2
- ECHDC2 | c.753G>T p.E251D (on ENST00000371522 / NM_001198961.2; = p.E220D on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV100597515, COSV64300763; called by muse, mutect2, varscan2
- ELOA2 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99796133; called by muse, mutect2
- EPO | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs1459236103, COSV99402533; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs775950025; called by mutect2, varscan2
- F5 | c.3703C>A p.L1235I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1262493507, COSV100888979; called by muse, mutect2, varscan2
- FAM120C | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV60259167; called by muse, mutect2, varscan2
- FAM126B | c.106dup p.T36Nfs*8 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs1355226466; called by mutect2, varscan2
- FAM149A | c.1142C>T p.P381L (on ENST00000356371 / NM_001367768.2; = p.P90L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99906411; called by muse, mutect2, varscan2
- FAT3 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99963148; called by muse, mutect2, varscan2
- FCRL3 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV100942956; called by muse, mutect2, varscan2
- FGG | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271752; called by muse, mutect2
- FLT1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374335323, COSV56723065, COSV99167652; called by muse, mutect2, varscan2
- FNDC11 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1402607373, COSV100918766; called by muse, mutect2, varscan2
- FOXD4 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs774722742, COSV100070702; called by muse, mutect2
- FOXD4L1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99380356; called by muse, mutect2
- FOXF1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1484329217, COSV52287715; called by muse, mutect2, varscan2
- FRMPD3 | c.2166G>T p.Q722H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99345830; called by muse, mutect2, varscan2
- FZR1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58051142; called by muse, mutect2
- GATAD2A | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99389792; called by muse, mutect2, varscan2
- GJA8 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs1426006227, COSV53789075; called by muse, mutect2, varscan2
- GMEB2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV99823504; called by muse, mutect2
- GRM4 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs773610073, COSV100945900; called by muse, mutect2, varscan2
- GSN | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767693759, COSV100375893; called by muse, mutect2, varscan2
- GUCY1A1 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99637335; called by muse, mutect2, varscan2
- H2BC14 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV60797715; called by muse, mutect2, varscan2
- HDAC10 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99352189; called by muse, mutect2, varscan2
- HDAC7 | c.545C>T p.A182V (on ENST00000427332; = p.A221V on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV50336555; called by muse, mutect2, varscan2
- HLA-DPA1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV101343099, COSV70089312; called by muse, mutect2, varscan2
- HLA-G | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV64407412; called by muse, mutect2, varscan2
- HLCS | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as rs967980306, COSV100357968; called by muse, mutect2, varscan2
- HSD17B7 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99597624; called by muse, mutect2, varscan2
- HSH2D | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV99507136; called by muse, mutect2, varscan2
- HTR5A | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs867712685, COSV55280975; called by muse, mutect2
- IGF2BP2 | c.178+2T>C p.X60_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100648907; called by muse, mutect2
- IKZF4 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56270997; called by muse, mutect2, varscan2
- IL20 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100894128; called by muse, mutect2, varscan2
- IL27RA | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99652011; called by muse, mutect2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs760925109; called by mutect2, pindel
- IRX5 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58059346; called by muse, mutect2
- ITGAL | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs756493723, COSV100776121; called by muse, mutect2, varscan2
- KDM6B | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs765171715, COSV54678370; called by muse, mutect2
- KRT5 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs752329142, COSV99357849; called by muse, mutect2, varscan2
- KY | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV101414955; called by muse, mutect2
- LEXM | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs202224828; called by muse, mutect2, varscan2
- MAP3K6 | c.3793G>T p.G1265W | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539207; called by muse, mutect2
- MAPK4 | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV101245224; called by muse, mutect2, varscan2
- ME3 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100042122, COSV60166491; called by muse, mutect2, varscan2
- MED13 | c.2175del p.K725Nfs*4 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as COSV67261860; called by mutect2, pindel, varscan2
- MED15 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.042); catalogued as COSV99487457; called by muse, mutect2, varscan2
- MGA | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV99578920; called by muse, mutect2
- MICAL2 | c.2956-1G>T p.X986_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99816868; called by muse, mutect2, varscan2
- MMP25 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs750900917, COSV60679069; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL10 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs369022041, COSV51619323; called by muse, mutect2, varscan2
- MTHFR | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100411668; called by muse, mutect2, varscan2
- MYO18B | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1446796047, COSV100122876; called by muse, mutect2
- MYO7B | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV101267955; called by muse, mutect2, varscan2
- MYPOP | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1399363630, COSV100447819; called by muse, mutect2, varscan2
- NEUROG3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV54343461; called by muse, mutect2, varscan2
- NFATC3 | c.2051A>G p.N684S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1034725861, COSV100284974; called by muse, mutect2, varscan2
- NLRC5 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV99346688; called by muse, mutect2
- NOS2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs754548662, COSV58221914; called by muse, mutect2, varscan2
- NR4A1 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751505484, COSV54485427; called by muse, varscan2
- NR4A1 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1304038471, COSV54481882; called by muse, varscan2
- NRK | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs769536438, COSV99686908; called by muse, mutect2, varscan2
- NSUN5 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs781919881, COSV53093174; called by muse, mutect2, varscan2
- OLR1 | c.69del p.A24Lfs*19 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs747703868; called by mutect2, pindel, varscan2
- OR51L1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100386377; called by muse, mutect2, varscan2
- PAQR9 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757779427, COSV61418252; called by muse, mutect2, varscan2
- PCDHA2 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65365768; called by muse, mutect2
- PCDHA5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV100972166; called by muse, mutect2
- PCDHB3 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV99164365; called by muse, mutect2, varscan2
- PEAK1 | c.4645A>G p.T1549A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1370063779, COSV100432619; called by muse, mutect2
- PEX16 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs749785179, COSV53799228; called by muse, mutect2, varscan2
- PI4KA | c.5501C>T p.T1834M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755332092, COSV55421362; called by muse, mutect2, varscan2
- PICALM | c.1810A>T p.T604S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100707740; called by muse, mutect2, varscan2
- PKD1L2 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100449681; called by muse, mutect2
- PPP1R12B | c.922-1G>T p.X308_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100406719; called by muse, mutect2, varscan2
- PPP1R32 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100087703; called by muse, mutect2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs764112302; called by mutect2, varscan2
- PSAPL1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as rs186026629; called by muse, varscan2
- PTCH2 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100941964; called by muse, mutect2, varscan2
- PTEN | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100909680, COSV64293534, COSV64307061; called by muse, mutect2, varscan2
- PTEN | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554893773, CM991079, COSV64292765, COSV64294921, COSV64304506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDN | c.3203C>T p.A1068V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765244831, COSV99412618; called by muse, mutect2, varscan2
- QRICH2 | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs1230415363, COSV99428885; called by mutect2, varscan2
- RALGAPB | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99484867; called by muse, mutect2, varscan2
- RANBP2 | c.6616G>T p.A2206S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV99311509; called by muse, mutect2, varscan2
- RAPGEF4 | c.2486C>T p.T829I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99910052; called by mutect2, varscan2
- RASEF | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1470025089, COSV64586492; called by muse, mutect2, varscan2
- RB1CC1 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99208140; called by muse, varscan2
- REV3L | c.9064T>C p.S3022P | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100725010; called by muse, mutect2
- RFC2 | c.566G>A p.R189Q (on ENST00000055077 / NM_181471.3; = p.R155Q on NM_002914.4) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277764; called by muse, mutect2, varscan2
- RIMBP2 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99898722; called by muse, mutect2, varscan2
- RNF144B | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs201463718, COSV99464349; called by muse, mutect2, varscan2
- RNF216 | c.222C>A p.Y74* (on ENST00000425013 / NM_207116.3; = p.Y131* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101111274; called by muse, mutect2, varscan2
- ROCK2 | c.4079G>A p.R1360Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as rs758748287, COSV100254312; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RREB1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100619203; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs759904440; called by mutect2, varscan2
- SBK2 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs760724693, COSV100705048; called by muse, mutect2, varscan2
- SCN1B | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as COSV99384920; called by muse, mutect2
- SCUBE1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1360829341, COSV100682985; called by muse, mutect2, varscan2
- SEC16A | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs753488642, COSV99256743; called by muse, mutect2, varscan2
- SGIP1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.166); catalogued as rs143844959; called by muse, mutect2, varscan2
- SIPA1L1 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100665260, COSV62173968; called by muse, mutect2, varscan2
- SKIV2L | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765151233, COSV100952648; called by muse, mutect2, varscan2
- SLC16A3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs1392799619, COSV101125889; called by muse, mutect2, varscan2
- SLC22A15 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV101047180; called by muse, mutect2
- SLC5A12 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1335956092, COSV101237617; called by muse, mutect2, varscan2
- SLCO1B3 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.159); catalogued as COSV53946083, COSV99681032; called by muse, mutect2
- SMC3 | c.1826T>C p.M609T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100699829; called by muse, mutect2, varscan2
- SMOC1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1322307106, COSV62763402; called by muse, mutect2
- SNX18 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV100410262; called by muse, mutect2
- SNX21 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99467409; called by muse, mutect2
- SOX2 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1270775176, COSV100327124; called by mutect2, varscan2
- SPEG | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200848544, COSV100403607; called by muse, mutect2, varscan2
- SPOCD1 | c.2737T>C p.W913R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929537; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE3 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV100515730; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs756457255; called by mutect2, varscan2
- TERT | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99717059; called by muse, mutect2, varscan2
- TFAP4 | c.528G>T p.V176= | Splice Region (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99200033; called by muse, mutect2, varscan2
- TLN1 | c.5972A>G p.D1991G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100147433; called by muse, mutect2
- TMIGD3 | c.290C>T p.A97V (on ENST00000369717 / NM_001081976.2; = p.A178V on NM_020683.7) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100778392; called by muse, mutect2, varscan2
- TMTC2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV100337652; called by muse, mutect2, varscan2
- TNFRSF25 | c.744G>A p.P248= | Splice Region (SNP) | VAF 15/50 reads (30%) | catalogued as rs1557725691, COSV100556280; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TOP2B | c.943A>C p.N315H (on ENST00000264331 / NM_001330700.2; = p.N310H on NM_001068.3) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV99979368; called by muse, mutect2, varscan2
- TPD52L1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV100509180; called by muse, mutect2
- TPM4 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100783681; called by muse, mutect2
- TPP2 | c.3577A>G p.K1193E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); catalogued as COSV101060200; called by muse, mutect2, varscan2
- TRPC7 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391101274, COSV61459664; called by muse, mutect2, varscan2
- TRPM3 | c.3775C>T p.Q1259* (on ENST00000357533 / NM_001366142.2; = p.Q1114* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100676892; called by muse, mutect2
- TSC1 | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53766473; called by muse, mutect2, varscan2
- TSPAN10 | c.457C>G p.P153A (on ENST00000574882 / NM_001290212.1; = p.P115A on NM_031945.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs753180923, COSV60773117; called by muse, mutect2
- TSPAN5 | c.86del p.L29Wfs*3 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs1484500770; called by mutect2, pindel, varscan2
- TST | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV99968159; called by muse, mutect2, varscan2
- TUBB6 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV52312975; called by muse, mutect2, varscan2
- UBE2C | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773029038, COSV54755069, COSV99708743; called by mutect2, varscan2
- UNC5D | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768683952, COSV54769558; called by muse, mutect2, varscan2
- UPF1 | c.1657G>A p.V553M (on ENST00000599848 / NM_001297549.2; = p.V542M on NM_002911.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs763426703, COSV99439002; called by muse, mutect2, varscan2
- URB2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs752766281, COSV50981941; called by muse, mutect2, varscan2
- USP5 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs781946029, COSV99978277; called by muse, mutect2, varscan2
- VSX2 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100001526; called by muse, mutect2, varscan2
- XDH | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV101052084; called by muse, mutect2, varscan2
- YARS2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as COSV100256335; called by muse, mutect2, varscan2
- ZAN | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV100769367; called by muse, mutect2, varscan2
- ZC3H13 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV54450706; called by muse, mutect2, varscan2
- ZFHX3 | c.5696del p.G1899Efs*15 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | catalogued as COSV51720026, COSV51738547; called by mutect2, pindel
- ZNF229 | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99350166; called by mutect2, varscan2
- ZNF253 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs760445174, COSV100849468; called by muse, varscan2
- ZNF418 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as COSV101268896; called by muse, mutect2, varscan2
- ZNF512 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs752256195, COSV62677922; called by muse, mutect2, varscan2
- ZNF768 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1319553802, COSV100776122, COSV100776143; called by muse, mutect2
- ZNF831 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1398530461, COSV100925865; called by muse, mutect2
- ZXDA | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62387919; called by muse, mutect2, varscan2
- ABHD8 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- BAIAP2L1 | c.1169del p.G390Vfs*19 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- CASD1 | c.2100dup p.A701Cfs*51 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- DCHS1 | c.1120del p.Q374Kfs*41 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- FAM219A | c.491_492del p.P164Qfs*39 (on ENST00000445726; = p.P147Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- FAT1 | c.7728del p.V2577Lfs*6 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- HDLBP | c.2429dup p.H811Afs*18 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- HIP1 | c.621_622del p.M208Vfs*29 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- HS2ST1 | c.250dup p.T84Nfs*12 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHV3-48 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, varscan2
- IGSF1 | c.1097del p.L366Wfs*17 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- KMT2C | c.4628del p.P1543Hfs*20 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- MBD6 | c.1472_1473del p.V491Afs*33 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by pindel, varscan2
- MFSD13A | c.1011del p.L338Sfs*41 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, varscan2
- MMP27 | c.210del p.F70Lfs*3 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by pindel, varscan2
- MYH7 | c.42del p.Y15Tfs*10 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- OR7C1 | c.849del p.M284Cfs*2 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- PARP14 | c.4996dup p.T1666Nfs*12 | Frame Shift Ins (INS) | VAF 22/45 reads (49%) | called by mutect2, varscan2
- PBRM1 | c.1248dup p.Y417Ifs*3 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- PPP4R3B | c.522dup p.L175Tfs*15 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- PTEN | c.294del p.E99Nfs*14 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- RB1 | c.1450_1451del p.M484Vfs*8 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by pindel, varscan2
- SAMD9L | c.936dup p.H313Tfs*5 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- SIK3 | c.1677dup p.R561Afs*42 (on ENST00000445177 / NM_001366686.2; = p.R567Afs*90 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- SLC35A2 | c.341dup p.L115Afs*13 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel, varscan2
- SLC9A8 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TSPAN19 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- UTP25 | c.2089del p.Y697Tfs*8 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- ABR | c.1278G>A p.P426= (on ENST00000302538 / NM_021962.5; = p.P389= on NM_001092.5) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs771879459, COSV52143290; called by muse, mutect2
- ACSBG1 | c.1416G>A p.A472= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs769179599, COSV51908186, COSV51909994; called by mutect2, varscan2
- ADAMTSL1 | c.2958C>T p.G986= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1434678993, COSV65888269; called by muse, mutect2, varscan2
- ADGRL1 | c.1062C>T p.R354= (on ENST00000340736 / NM_001008701.3; = p.R349= on NM_014921.5) | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs201969754, COSV100529333; called by muse, mutect2, varscan2
- AGO2 | c.2466T>C p.H822= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99595367; called by muse, mutect2, varscan2
- AGRN | c.4632C>T p.G1544= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1174638162, COSV101038657; called by muse, mutect2
- ANO10 | c.1083G>A p.V361= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1274623516, COSV99428255; called by muse, mutect2
- AP3D1 | c.501G>A p.V167= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100642457; called by muse, mutect2
- APOA1 | c.150C>T p.G50= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99369160; called by muse, mutect2, varscan2
- ARHGAP22 | c.1080G>A p.P360= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs1464470465, COSV99984667; called by muse, mutect2
- ATP2C2 | c.1188G>A p.T396= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs146656709; called by muse, mutect2
- BANP | c.1020G>A p.S340= (on ENST00000286122; = p.S309= on NM_017869.4) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs757698946, COSV99621058; called by muse, mutect2, varscan2
- BCL11A | c.2196C>T p.G732= (on ENST00000335712 / NM_001365609.1; = p.G766= on NM_022893.4) | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV59626823; called by muse, mutect2, varscan2
- BTLA | c.753C>T p.N251= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1271336191, COSV100569636; called by muse, mutect2, varscan2
- CCL7 | c.171C>T p.S57= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99565485; called by muse, mutect2, varscan2
- CELSR1 | c.3663C>T p.S1221= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99417230; called by muse, mutect2
- CEP41 | c.360G>A p.P120= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs148169407; called by muse, mutect2, varscan2
- CES2 | c.639C>T p.A213= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV100399106; called by muse, mutect2, varscan2
- CFAP44 | c.918C>A p.T306= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99868930, COSV99869126; called by muse, mutect2, varscan2
- CIAO3 | c.1083G>A p.L361= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1299057954, COSV99284615; called by muse, mutect2
- CLEC16A | c.1185C>T p.N395= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs770709204, COSV68499591; called by muse, mutect2, varscan2
- COL7A1 | c.5133A>G p.T1711= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV100095374; called by muse, mutect2, varscan2
- CP | c.582C>T p.I194= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV52831833; called by muse, mutect2, varscan2
- CSDC2 | c.414C>T p.A138= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs751037652, COSV99348053; called by muse, mutect2, varscan2
- CSMD3 | c.1047C>A p.T349= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99827901; called by muse, mutect2
- CYP2S1 | c.918G>A p.T306= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs766003336, COSV59505409; called by muse, mutect2, varscan2
- CYTH2 | c.57G>A p.L19= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs766615487, COSV100287075; called by muse, mutect2, varscan2
- DAXX | c.555G>A p.R185= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99801649; called by muse, mutect2, varscan2
- DENND2A | c.861C>T p.I287= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs781077093, COSV52050090, COSV52054666; called by muse, mutect2, varscan2
- DENND2B | c.2466C>T p.S822= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs769711435, COSV100567255; called by muse, varscan2
- DIDO1 | c.1842C>T p.A614= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99825117; called by muse, mutect2
- DYRK4 | c.1479C>T p.V493= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1412574025, COSV99155556; called by muse, mutect2
- EDEM2 | c.1708C>T p.L570= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1444292467, COSV100787994; called by muse, mutect2
- ENO3 | c.339C>T p.G113= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs941236828, COSV56697884; called by muse, mutect2, varscan2
- F12 | c.13C>T p.L5= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99499505; called by muse, mutect2
- FAM220A | c.309C>T p.A103= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs768824416, COSV100510760; called by muse, mutect2, varscan2
- FAM47C | c.348G>A p.A116= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV63724669; called by muse, mutect2, varscan2
- FANCB | c.504C>A p.S168= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100146441; called by mutect2, varscan2
- FBN3 | c.7329C>A p.T2443= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99560213; called by muse, mutect2, varscan2
- FBXL19 | c.1785C>T p.H595= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs750906996, COSV100590901; called by muse, mutect2, varscan2
- FBXL7 | c.1219C>T p.L407= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100309307, COSV61653152; called by muse, mutect2
- GIMAP1 | c.393G>A p.A131= | Silent (SNP) | VAF 4/75 reads (5%) | catalogued as rs1462752546, COSV56190527; called by muse, mutect2
- GPAT4 | c.1117C>T p.L373= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV101213904; called by muse, mutect2, varscan2
- HDHD5 | c.1122G>A p.T374= (on ENST00000336737 / NM_033070.3; = p.T344= on NM_017829.5) | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs777747214, COSV50096135, COSV99324550; called by muse, mutect2
- HPS6 | c.1603C>T p.L535= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV54626929; called by muse, mutect2
- IGKV6D-41 | c.309T>C p.A103= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- INHBB | c.813G>A p.S271= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs778038309, COSV54677428; called by muse, mutect2, varscan2
- KRTAP1-5 | c.396C>T p.P132= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- LHB | c.423C>G p.L141= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV55487741, COSV99668878; called by muse, mutect2, varscan2
- LSM14B | c.405G>A p.Q135= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs768015479, COSV99443914; called by muse, mutect2, varscan2
- MFSD2B | c.991C>T p.L331= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100601001; called by muse, mutect2
- MYH7 | c.1195C>T p.L399= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV62523649; called by muse, mutect2
- MYO10 | c.1557C>T p.T519= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101569768; called by muse, mutect2, varscan2
- NR3C2 | c.2304G>A p.T768= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs762876416, COSV100678794; called by muse, mutect2, varscan2
- PACS2 | c.2616G>A p.S872= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs782114007, COSV100330631; called by muse, mutect2, varscan2
- PAPPA | c.4098G>A p.K1366= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV100073196; called by muse, mutect2
- PAPSS1 | c.627A>C p.V209= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99491847; called by muse, mutect2, varscan2
- PCDHA1 | c.699C>T p.L233= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1230076426, COSV65373715; called by muse, mutect2, varscan2
- PHLDB1 | c.3243G>A p.S1081= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs781835272, COSV100616344, COSV61878764; called by muse, mutect2, varscan2
- PLAU | c.798C>T p.S266= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs767978842, COSV101032270; called by muse, mutect2, varscan2
- PLCB3 | c.2322C>T p.P774= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs761637040, COSV99657216; called by muse, mutect2, varscan2
- PLCH1 | c.2442C>T p.H814= (on ENST00000340059 / NM_001130960.2; = p.H826= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1032307178, COSV100395967; called by muse, mutect2
- PRAMEF20 | c.531A>G p.L177= | Silent (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
- PRKD2 | c.300C>G p.P100= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99354159; called by muse, mutect2, varscan2
- RABL6 | c.657C>T p.G219= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1382280872, COSV100272986; called by muse, mutect2, varscan2
- RAD51 | c.954C>A p.P318= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99139150; called by muse, mutect2
- RADIL | c.1341G>A p.S447= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs1322415359, COSV101271298; called by muse, mutect2, varscan2
- RASAL3 | c.2130G>A p.Q710= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99652790; called by muse, mutect2, varscan2
- RBM4 | c.192C>T p.N64= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs934877737, COSV100029549; called by muse, mutect2, varscan2
- RELT | c.1041G>T p.V347= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as rs1006691677, COSV99292719; called by muse, mutect2
- RIOK3 | c.24G>C p.S8= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV100259208; called by muse, mutect2
- RNF149 | c.855G>T p.L285= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99766473; called by muse, mutect2
- ROBO4 | c.2377C>T p.L793= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100127362; called by muse, mutect2, varscan2
- RPRM | c.189C>T p.C63= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100371520; called by muse, mutect2, varscan2
- RSRC2 | c.571A>C p.R191= | Silent (SNP) | VAF 8/133 reads (6%) | catalogued as COSV100063394; called by muse, mutect2
- RTTN | c.999G>A p.A333= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs755744735, COSV55345494; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC16A | c.183G>A p.A61= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs755607943, COSV99256744; called by muse, mutect2, varscan2
- SEMA3C | c.765G>A p.T255= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs369076469; called by muse, mutect2, varscan2
- SHANK2 | c.3402C>T p.D1134= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs149101502; called by muse, mutect2, varscan2
- SLC20A1 | c.1053A>G p.A351= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as rs1171143233, COSV99733920; called by muse, mutect2
- SLC45A1 | c.1317C>A p.S439= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99238455; called by muse, mutect2
- SPATA31A1 | c.945T>C p.G315= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- SRCAP | c.9286T>C p.L3096= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99349554; called by muse, mutect2
- STARD8 | c.1701G>A p.Q567= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99366371; called by muse, mutect2
- TENM3 | c.690C>T p.P230= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs758152460, COSV101304945; called by muse, mutect2, varscan2
- TMEM43 | c.483C>T p.F161= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs772842801, COSV60145835; called by muse, mutect2, varscan2
- TNRC18 | c.6057C>A p.P2019= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101269579; called by muse, mutect2
- TRAM2 | c.69G>A p.A23= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99480038; called by muse, mutect2
- TRAPPC3 | c.63G>A p.L21= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100920300; called by muse, mutect2, varscan2
- TRO | c.3813C>T p.G1271= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs368748764, COSV99435974; called by muse, mutect2, varscan2
- TSBP1 | c.882C>T p.D294= (on ENST00000617061; = p.D297= on NM_006781.5) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs373884140; called by muse, mutect2, varscan2
- TSPAN13 | c.556C>T p.L186= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs769178778, COSV100018026; called by muse, mutect2, varscan2
- UBAC2 | c.402G>A p.V134= (on ENST00000403766 / NM_001144072.2; = p.V99= on NM_177967.4) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs369781516; called by muse, mutect2, varscan2
- WNT10B | c.120G>A p.P40= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV99975789; called by muse, mutect2, varscan2
- XAB2 | c.957C>T p.R319= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV64321410; called by muse, mutect2
- ZIC4 | c.879G>A p.P293= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV101267818; called by muse, mutect2, varscan2
- ZNF483 | c.1434T>C p.D478= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100492696; called by muse, mutect2, varscan2
- ZNF532 | c.3534G>T p.V1178= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs763270020, COSV60173974; called by mutect2, varscan2
- ZSCAN25 | c.1431G>A p.R477= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1197255670, COSV99500458; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532292 C>T | 5'Flank (SNP) | VAF 22/69 reads (32%) | catalogued as rs922617206, COSV101587385; called by muse, mutect2, varscan2
- BABAM2 | c.1088+11601A>G | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100567469; called by muse, mutect2, varscan2
- CDC20B | c.126+1882C>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57049816, COSV99696635; called by muse, mutect2
- MYADM | chr19:53874388 G>A | 3'Flank (SNP) | VAF 9/104 reads (9%) | catalogued as rs1224679404, COSV100424981, COSV61240542; called by muse, mutect2
- PKD1L2 | n.276C>T | RNA (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- SCN5A | c.612-163A>G | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100346971; called by muse, varscan2
